Gene-level copy-number profile of tumor specimen MP2PRT-PAVUCJ-TMP1-A from MP2PRT case MP2PRT-PAVUCJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (965 days).
Specimen MP2PRT-PAVUCJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b9de9b09-8484-42a8-9613-11e2bd4be527.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVUCJ-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/90f1a38f-9599-45d4-ada4-275851a44fb3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 488; copy number 2: 57,753; copy number 3: 102.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,295,455, 42 genes (within-gene range 0–2): IGKC, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36.
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–1): IGHVIII-47-1, IGHV3-48.
- chr14:106,564,375–106,579,236, 3 genes (within-gene range 0–2): IGHVII-49-1, IGHV3-50, IGHV5-51.
- chr14:106,584,718–106,606,551, 6 genes (within-gene range 0–2): IGHVII-51-2, IGHV3-52, IGHV3-53, IGHVII-53-1, IGHV3-54, IGHV4-55.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 488. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
